Somatic mutation profile of tumor specimen TCGA-AB-2890-03A (aliquot TCGA-AB-2890-03A-01W-0732-08) from TCGA case TCGA-AB-2890, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.1 years (25,234 days).
Specimen TCGA-AB-2890-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebf1d5a5-7f7b-488a-9d37-37d43b804e05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2890-11A (Solid Tissue Normal), aliquot TCGA-AB-2890-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a0d99e4-9dec-409a-b0fc-8de0a0e9a36f

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADNP | c.2146A>C p.K716Q | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.234); catalogued as COSV62424570; called by muse, mutect2, varscan2
- CNOT6L | c.1255G>A p.V419I (on ENST00000504123 / NM_001286790.2; = p.V414I on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53697485; called by mutect2, varscan2
- LRIT1 | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs375523621; called by muse, mutect2, varscan2
- STAT5A | c.2129_2139del p.S710Wfs*23 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- ADAP1 | c.786G>A p.T262= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs139452042, COSV56210435; called by muse, mutect2, varscan2
